Gene-level copy-number profile of tumor specimen TCGA-D1-A16S-01A from TCGA case TCGA-D1-A16S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 70.3 years (25,690 days).
Specimen TCGA-D1-A16S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.08fc4f13-5ebb-4549-9d9b-895a15fd1395.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A16S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/624a28a7-bb92-4cdb-982d-e28a399bdca5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 3,437; copy number 2: 12,368; copy number 3: 17,085; copy number 4: 19,359; copy number 5: 5,215; copy number 6: 1,575; copy number 7: 271; copy number 8: 69; copy number 9: 18; copy number 10: 352; copy number 11: 15; copy number 13: 25; copy number 19: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A16S-01A-11D-A12G-01): tumor purity 0.71, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:110,590,082–110,592,204, 1 gene: AC073326.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 432 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:34,853,094–36,697,867, 37 genes, copy number 11–19: APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr17:39,757,718–40,115,442, 18 genes, copy number 9 (within-gene range 8–12): IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1.
- chr19:8,721,634–15,348,417, 377 genes, copy number 10–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
